Gene-level copy-number profile of tumor specimen TCGA-BR-A4J4-01A from TCGA case TCGA-BR-A4J4, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 39.6 years (14,459 days).
Specimen TCGA-BR-A4J4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.ce3b06af-8447-4e64-8fb0-66637dfb7d61.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BR-A4J4-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/45014e80-94c0-425b-b95d-53e939ae0123

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 2: 4,940; copy number 4: 41,602; copy number 6: 12,538; copy number 7: 24; copy number 8: 395; copy number 9: 298; copy number 122: 8; copy number 168: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BR-A4J4-01A-12D-A253-01): tumor purity 0.45, ploidy 2.19, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 307 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:176,415,439–176,867,838, 1 gene, copy number 9 (within-gene range 6–9): LINC01208.
- chr3:176,763,233–192,119,864, 296 genes, copy number 9 (broad region; genes not listed).
- chr3:192,238,037–192,283,097, 1 gene, copy number 9: FGF12-AS1.
- chr17:37,609,739–37,643,446, 1 gene, copy number 168 (within-gene range 4–168): DDX52.
- chr17:37,642,947–37,940,790, 8 genes, copy number 122 (within-gene range 122–168): AC243571.2, AC243585.1, HNF1B, AC243571.1, YWHAEP7, RNU6-489P, TBC1D3K, 5S_rRNA.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
